Somatic mutation profile of tumor specimen CDDP-ABJ4-TTP2-A (aliquot CDDP-ABJ4-TTP2-A-1-0-D-A500-36) from CDDP_EAGLE case CDDP-ABJ4, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 68 years.
Specimen CDDP-ABJ4-TTP2-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4477cc6c-780a-40a7-b1f4-6e33d02fc481.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CDDP-ABJ4-NB1-A (Blood Derived Normal), aliquot CDDP-ABJ4-NB1-A-1-0-D-A500-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6bd3ecf7-fbb5-4489-9f8f-51091ab6cfbc

The open-access MAF lists 275 somatic variants for this specimen: 193 protein-altering or splice-affecting, 47 silent, 35 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 162, Silent 47, Nonsense Mutation 20, Intron 16, RNA 15, Frame Shift Del 6, Splice Site 3, 3'Flank 2, 5'Flank 1, In Frame Del 1, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STK11 | c.493G>T p.E165* | Nonsense Mutation (SNP) | VAF 32/66 reads (48%) | hotspot (GDC flag); catalogued as rs1359582062, CD051785, CM044076, COSV58820485, COSV58828619, COSV58831044; called by muse, mutect2, varscan2
- ABCA4 | c.658C>A p.R220S | Missense Mutation (SNP) | VAF 67/171 reads (39%) | SIFT tolerated (0.72); PolyPhen benign (0.039); catalogued as CM015069, COSV64671902, COSV64673084; called by muse, mutect2, varscan2
- AC131160.1 | c.536T>C p.V179A | Missense Mutation (SNP) | VAF 65/222 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV57700567; called by muse, mutect2, varscan2
- ACTBL2 | c.308C>A p.P103H | Missense Mutation (SNP) | VAF 95/276 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV70661207; called by muse, mutect2, varscan2
- ACTL6B | c.1012C>T p.R338C | Missense Mutation (SNP) | VAF 67/185 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs371931775, COSV50513954; called by muse, mutect2, varscan2
- ADAMTS20 | c.5450C>T p.T1817M | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as rs770174733, COSV67125728; called by muse, mutect2, varscan2
- ANO1 | c.2631C>G p.Y877* | Nonsense Mutation (SNP) | VAF 45/159 reads (28%) | catalogued as COSV62445508, COSV62447157; called by muse, mutect2, varscan2
- ANO10 | c.1253A>G p.Y418C | Missense Mutation (SNP) | VAF 56/172 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748489030, COSV52730715; called by muse, mutect2, varscan2
- ARHGAP31 | c.3524G>C p.R1175P | Missense Mutation (SNP) | VAF 83/277 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51792219, COSV51797736; called by muse, mutect2, varscan2
- ARHGEF37 | c.1669G>A p.G557R | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1258539437, COSV61368617; called by muse, mutect2
- ARNTL | c.888G>A p.M296I (on ENST00000403290 / NM_001297719.2; = p.M295I on NM_001178.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 99/317 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0.042); catalogued as COSV62986348; called by muse, mutect2, varscan2
- ATP8B4 | c.2715G>T p.W905C | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV52714228; called by muse, mutect2, varscan2
- BCL11B | c.1552C>G p.R518G (on ENST00000357195 / NM_001282237.2; = p.R447G on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/212 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.292); catalogued as COSV61735245; called by muse, mutect2, varscan2
- BMP6 | c.1077G>T p.M359I | Missense Mutation (SNP) | VAF 91/558 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV51664585; called by muse, mutect2, varscan2
- C20orf203 | c.413G>T p.G138V | Missense Mutation (SNP) | VAF 54/160 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.98); catalogued as COSV62531125; called by muse, mutect2, varscan2
- CACNA1G | c.5834G>A p.W1945* | Nonsense Mutation (SNP) | VAF 53/125 reads (42%) | catalogued as COSV100661495, COSV61725583; called by muse, mutect2, varscan2
- CACNA1S | c.5476G>C p.E1826Q | Missense Mutation (SNP) | VAF 196/380 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV62938926; called by muse, mutect2, varscan2
- CATSPER4 | c.1234C>T p.Q412* | Nonsense Mutation (SNP) | VAF 43/145 reads (30%) | catalogued as COSV58792927; called by muse, mutect2, varscan2
- CEP112 | c.2773G>A p.D925N (on ENST00000392769 / NM_001353127.1; = p.D181N on NM_001037325.3) | Missense Mutation (SNP) | VAF 42/162 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV58063710; called by muse, mutect2, varscan2
- CFAP20DC | c.1570T>A p.Y524N (on ENST00000482387 / NM_001351530.2; = p.Y399N on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/148 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.06); catalogued as COSV55919132; called by muse, mutect2, varscan2
- CLASP1 | c.3539G>T p.S1180I | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55322269; called by muse, mutect2, varscan2
- COL6A3 | c.3019C>T p.P1007S | Missense Mutation (SNP) | VAF 86/200 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.168); catalogued as COSV55087576; called by muse, mutect2, varscan2
- COP1 | c.1477G>T p.G493C | Missense Mutation (SNP) | VAF 29/189 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV58166360; called by muse, mutect2, varscan2
- CPM | c.605A>G p.N202S | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.368); catalogued as rs1411241379; called by mutect2, varscan2
- CRB1 | c.1427C>A p.T476N | Missense Mutation (SNP) | VAF 89/463 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV66328642, COSV66329795; called by muse, mutect2, varscan2
- CYLC1 | c.88C>A p.Q30K | Missense Mutation (SNP) | VAF 28/45 reads (62%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.475); catalogued as COSV61410802, COSV61411651; called by muse, mutect2, varscan2
- CYP4F22 | c.622C>A p.L208M | Missense Mutation (SNP) | VAF 153/433 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54108075; called by muse, mutect2, varscan2
- DCLK2 | c.428G>C p.S143T | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV56203304; called by mutect2, varscan2
- DCP1B | c.1414G>T p.A472S | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV54968659; called by muse, mutect2, varscan2
- DOCK10 | c.6267C>A p.Y2089* | Nonsense Mutation (SNP) | VAF 30/103 reads (29%) | catalogued as COSV51384415; called by muse, mutect2, varscan2
- DPPA2 | c.262A>G p.I88V | Missense Mutation (SNP) | VAF 83/232 reads (36%) | SIFT tolerated (0.98); PolyPhen benign (0.045); catalogued as COSV72118042; called by muse, mutect2, varscan2
- DST | c.21955G>T p.A7319S (on ENST00000361203 / NM_001374722.1; = p.A4992S on NM_015548.5) | Missense Mutation (SNP) | VAF 82/123 reads (67%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV55010743; called by muse, mutect2, varscan2
- DYNC2H1 | c.2580G>T p.W860C | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs765676542, COSV62089946; called by muse, mutect2, varscan2
- EPHB3 | c.2639A>C p.N880T | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.996); catalogued as rs1255811150, COSV57805529; called by muse, mutect2, varscan2
- ETV6 | c.157C>T p.H53Y | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.937); catalogued as CM1511678, COSV67149635; called by muse, mutect2, varscan2
- FAM135B | c.3296A>T p.K1099I | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52720928; called by muse, varscan2
- FAT3 | c.11995C>A p.Q3999K | Missense Mutation (SNP) | VAF 59/209 reads (28%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.605); catalogued as COSV53072761, COSV53103429; called by muse, mutect2, varscan2
- FAT4 | c.2995C>T p.L999F | Missense Mutation (SNP) | VAF 64/166 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.35); catalogued as COSV67885159; called by muse, mutect2, varscan2
- FSHR | c.781C>G p.L261V | Missense Mutation (SNP) | VAF 115/307 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as rs766651226, COSV58622490; called by muse, mutect2, varscan2
- GABRA3 | c.644C>A p.T215K | Missense Mutation (SNP) | VAF 35/52 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); catalogued as COSV64798095; called by muse, mutect2, varscan2
- GIN1 | c.981G>A p.M327I | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs782269685, COSV67536787; called by muse, mutect2, varscan2
- GJA10 | c.988G>T p.G330* | Nonsense Mutation (SNP) | VAF 78/143 reads (55%) | catalogued as COSV65355114; called by muse, mutect2, varscan2
- GLI2 | c.1178C>T p.T393M | Missense Mutation (SNP) | VAF 70/224 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.25); catalogued as rs571690193, COSV58045775; ClinVar: uncertain significance; called by muse, varscan2
- GNAS | c.955G>C p.D319H | Missense Mutation (SNP) | VAF 55/156 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as COSV58333540; called by muse, mutect2, varscan2
- GRIN3A | c.2068G>A p.V690I | Missense Mutation (SNP) | VAF 84/262 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs376247266, COSV104422445; called by muse, mutect2, varscan2
- GRIPAP1 | c.577G>T p.E193* | Nonsense Mutation (SNP) | VAF 16/26 reads (62%) | catalogued as COSV64552971; called by muse, mutect2, varscan2
- H2AC6 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 113/730 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.92); catalogued as COSV58415749; called by muse, mutect2, varscan2
- HACE1 | c.911A>G p.H304R | Missense Mutation (SNP) | VAF 76/133 reads (57%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.888); catalogued as COSV53501875; called by muse, mutect2, varscan2
- HAVCR1 | c.40C>A p.L14M | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV59399475; called by muse, mutect2, varscan2
- HCN1 | c.1271C>A p.P424Q | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57507099; called by muse, mutect2, varscan2
- HDAC9 | c.854G>C p.S285T | Missense Mutation (SNP) | VAF 38/149 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV67772177; called by muse, mutect2, varscan2
- HPN | c.769G>T p.D257Y | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52883349, COSV52886079; called by muse, mutect2, varscan2
- IFNA8 | c.188A>T p.Q63L | Missense Mutation (SNP) | VAF 66/198 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.042); catalogued as COSV66504548; called by muse, mutect2, varscan2
- IGSF11 | c.331C>T p.Q111* (on ENST00000393775 / NM_001015887.3; = p.Q110* on NM_152538.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 89/263 reads (34%) | catalogued as COSV61178304; called by muse, mutect2, varscan2
- IL4R | c.1025G>A p.C342Y | Missense Mutation (SNP) | VAF 72/253 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs748338395, COSV50141927; called by muse, mutect2, varscan2
- INPP5F | c.3109C>T p.Q1037* | Nonsense Mutation (SNP) | VAF 70/338 reads (21%) | catalogued as COSV100739934; called by muse, mutect2, varscan2
- IQCF1 | c.368G>T p.R123L | Missense Mutation (SNP) | VAF 82/200 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.322); catalogued as COSV58823362, COSV58824203; called by muse, varscan2
- JMJD8 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.909); catalogued as rs566921908, COSV50196275; called by muse, mutect2, varscan2
- KANK1 | c.3361G>T p.E1121* | Nonsense Mutation (SNP) | VAF 54/136 reads (40%) | catalogued as rs779136001, COSV63211819; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNH4 | c.1352C>A p.A451E | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV52915167, COSV52916974; called by muse, mutect2
- KLF11 | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 57/139 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs541774526, COSV59940424; called by muse, mutect2, varscan2
- KLHL1 | c.1488G>C p.R496S | Missense Mutation (SNP) | VAF 90/300 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64771441; called by muse, mutect2, varscan2
- KLHL6 | c.663C>G p.I221M | Missense Mutation (SNP) | VAF 115/305 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as COSV58068892; called by muse, mutect2, varscan2
- LOXHD1 | c.2486G>T p.G829V | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.338); catalogued as COSV56063277; called by muse, mutect2, varscan2
- LRR1 | c.552G>C p.L184F | Missense Mutation (SNP) | VAF 56/146 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770191229; called by muse, mutect2, varscan2
- MAGEA10 | c.967C>A p.P323T | Missense Mutation (SNP) | VAF 120/165 reads (73%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as COSV54883741; called by muse, mutect2, varscan2
- MAPK8IP2 | c.1926C>A p.F642L | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV50498885; called by muse, mutect2, varscan2
- MASP1 | c.1366C>T p.Q456* | Nonsense Mutation (SNP) | VAF 67/178 reads (38%) | catalogued as COSV56223109; called by muse, mutect2, varscan2
- MBL2 | c.740C>G p.P247R | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV64758292, COSV64758839; called by muse, mutect2, varscan2
- MCOLN2 | c.1148G>A p.G383E | Missense Mutation (SNP) | VAF 40/140 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs746779517, COSV52295337; called by muse, mutect2, varscan2
- MEGF10 | c.274T>A p.S92T | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV57248456; called by muse, mutect2, varscan2
- MEIOC | c.1291C>G p.P431A | Missense Mutation (SNP) | VAF 63/221 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV63439885; called by muse, mutect2, varscan2
- MFN2 | c.436C>G p.L146V | Missense Mutation (SNP) | VAF 88/241 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.513); catalogued as CM118413, COSV52422103; called by muse, mutect2, varscan2
- MMP15 | c.1082G>A p.R361Q | Missense Mutation (SNP) | VAF 68/138 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as rs376327026; called by muse, varscan2
- MN1 | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 49/155 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.116); catalogued as COSV56557951; called by muse, mutect2, varscan2
- MTHFD2 | c.648T>A p.D216E | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); catalogued as COSV51201327; called by muse, mutect2, varscan2
- MTTP | c.1876C>G p.R626G | Missense Mutation (SNP) | VAF 149/404 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.026); catalogued as COSV55505486; called by muse, mutect2, varscan2
- MYO18B | c.7486C>A p.P2496T | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as COSV59132313; called by muse, mutect2, varscan2
- NEK1 | c.1475C>T p.A492V | Missense Mutation (SNP) | VAF 51/191 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.054); catalogued as COSV71455812; called by muse, mutect2, varscan2
- NEK10 | c.883G>T p.V295F | Missense Mutation (SNP) | VAF 99/328 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV58282716; called by muse, mutect2, varscan2
- NEO1 | c.2851G>C p.E951Q | Missense Mutation (SNP) | VAF 65/121 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56070553; called by muse, mutect2, varscan2
- NFASC | c.28G>T p.V10F | Missense Mutation (SNP) | VAF 86/133 reads (65%) | SIFT tolerated (0.18); PolyPhen benign (0.438); catalogued as rs766992555, COSV58364184; called by muse, mutect2, varscan2
- NLRP6 | c.1919G>T p.R640L | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV56459160, COSV56459330; called by muse, mutect2, varscan2
- NLRP7 | c.2008C>G p.L670V | Missense Mutation (SNP) | VAF 134/217 reads (62%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV60173684; called by muse, mutect2, varscan2
- NR3C1 | c.2083A>G p.K695E | Missense Mutation (SNP) | VAF 74/187 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV51542379; called by muse, mutect2, varscan2
- NRXN1 | c.1514C>T p.S505L | Missense Mutation (SNP) | VAF 133/397 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58440869, COSV58450740; called by muse, mutect2, varscan2
- NUP214 | c.4825G>A p.V1609I | Missense Mutation (SNP) | VAF 12/374 reads (3%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs902919600; called by muse, mutect2
- NWD2 | c.3655C>A p.L1219M | Missense Mutation (SNP) | VAF 106/314 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV58750890; called by muse, mutect2, varscan2
- OR1A1 | c.408G>T p.M136I | Missense Mutation (SNP) | VAF 105/330 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV58403634; called by muse, mutect2, varscan2
- OR1L6 | c.389C>G p.S130C (on ENST00000373684; = p.S94C on NM_001004453.2) | Missense Mutation (SNP) | VAF 121/331 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV59028365, COSV59028481; called by muse, mutect2, varscan2
- OR2W3 | c.643C>G p.L215V | Missense Mutation (SNP) | VAF 38/272 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV64456706; called by muse, mutect2, varscan2
- OR4C6 | c.436G>T p.A146S | Missense Mutation (SNP) | VAF 60/187 reads (32%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.305); catalogued as rs778706066, COSV58603532; called by muse, mutect2, varscan2
- OR5AR1 | c.605T>A p.L202Q | Missense Mutation (SNP) | VAF 80/217 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.473); catalogued as COSV57253665; called by muse, mutect2, varscan2
- OTOF | c.1684G>T p.G562C | Missense Mutation (SNP) | VAF 99/275 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55501594; called by muse, mutect2, varscan2
- PCDH7 | c.271A>G p.I91V | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV62338416; called by muse, mutect2, varscan2
- PCDH7 | c.1177C>A p.P393T | Missense Mutation (SNP) | VAF 51/175 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.078); catalogued as rs764741351, COSV62338432; called by muse, mutect2, varscan2
- PCLO | c.9445G>A p.A3149T | Missense Mutation (SNP) | VAF 64/191 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.096); catalogued as COSV61618085, COSV61677752; called by muse, mutect2, varscan2
- PCSK4 | c.1636G>A p.E546K | Missense Mutation (SNP) | VAF 36/58 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772832448, COSV56299070; called by muse, mutect2, varscan2
- PDE11A | c.2676G>T p.K892N | Missense Mutation (SNP) | VAF 112/330 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.021); catalogued as COSV53692899; called by muse, mutect2, varscan2
- PDZRN4 | c.1511A>G p.E504G (on ENST00000402685 / NM_001164595.2; = p.E246G on NM_013377.4) | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); catalogued as COSV54199420; called by muse, mutect2
- PDZRN4 | c.1513G>A p.E505K (on ENST00000402685 / NM_001164595.2; = p.E247K on NM_013377.4) | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as COSV54199459; called by muse, mutect2
- PLCH1 | c.1858G>T p.G620* (on ENST00000340059 / NM_001130960.2; = p.G632* on NM_014996.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 31/76 reads (41%) | catalogued as COSV58193589; called by muse, mutect2, varscan2
- POSTN | c.1048G>T p.D350Y | Missense Mutation (SNP) | VAF 59/192 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65712798; called by muse, mutect2, varscan2
- PRDM5 | c.1883C>A p.A628D | Missense Mutation (SNP) | VAF 103/310 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.368); catalogued as COSV53359598; called by muse, mutect2, varscan2
- PRELP | c.763G>C p.E255Q | Missense Mutation (SNP) | VAF 72/415 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.271); catalogued as COSV58115513; called by muse, mutect2, varscan2
- PTGER2 | c.319C>A p.R107S | Missense Mutation (SNP) | VAF 65/159 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0.191); catalogued as COSV55418784; called by muse, mutect2, varscan2
- RERE | c.2138C>T p.P713L | Missense Mutation (SNP) | VAF 54/159 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs764104299, COSV61941296; called by muse, mutect2, varscan2
- RHCG | c.962T>A p.F321Y | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated (0.79); PolyPhen benign (0.034); catalogued as COSV51515623; called by muse, mutect2, varscan2
- RNF133 | c.1075C>T p.Q359* | Nonsense Mutation (SNP) | VAF 25/69 reads (36%) | catalogued as COSV57388211; called by muse, mutect2, varscan2
- ROBO2 | c.1728G>T p.K576N | Missense Mutation (SNP) | VAF 150/439 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV59908687; called by muse, mutect2, varscan2
- RORB | c.430C>A p.L144M (on ENST00000396204 / NM_001365023.1; = p.L133M on NM_006914.4) | Missense Mutation (SNP) | VAF 66/189 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.866); catalogued as rs1355179821, COSV65335387; called by muse, mutect2, varscan2
- RORB | c.431T>A p.L144Q (on ENST00000396204 / NM_001365023.1; = p.L133Q on NM_006914.4) | Missense Mutation (SNP) | VAF 64/187 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.905); catalogued as COSV65335397; called by muse, mutect2, varscan2
- RSF1 | c.1283T>A p.I428N | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV57839161; called by muse, mutect2, varscan2
- RYR3 | c.14205C>A p.D4735E (on ENST00000389232; = p.D4736E on NM_001036.6) | Missense Mutation (SNP) | VAF 44/167 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV66786365; called by muse, mutect2, varscan2
- SCARA3 | c.1649G>T p.G550V | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57270024; called by muse, mutect2, varscan2
- SETD2 | c.7136C>T p.P2379L | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs200186997, COSV57436484; called by muse, mutect2
- SGO2 | c.2653G>T p.E885* | Nonsense Mutation (SNP) | VAF 15/37 reads (41%) | catalogued as COSV63415039; called by muse, mutect2, varscan2
- SHANK3 | c.1760C>T p.P587L | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1165335549, COSV99436239; called by muse, mutect2, varscan2
- SLC12A3 | c.1003G>T p.G335C | Missense Mutation (SNP) | VAF 84/259 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52634460; called by muse, mutect2, varscan2
- SLC4A7 | c.2876G>T p.G959V | Missense Mutation (SNP) | VAF 43/127 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as COSV55396828; called by muse, mutect2, varscan2
- SMARCC2 | c.1418A>G p.Y473C | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57217668; called by muse, mutect2, varscan2
- SPATA19 | c.383C>G p.P128R | Missense Mutation (SNP) | VAF 45/146 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.61); catalogued as COSV54483162; called by muse, mutect2, varscan2
- SPATA31A6 | c.1465C>T p.P489S | Missense Mutation (SNP) | VAF 254/353 reads (72%) | SIFT tolerated (0.31); PolyPhen benign (0.384); catalogued as rs202002661, COSV60535687; called by muse, mutect2, varscan2
- SPINK2 | c.71A>T p.Q24L | Missense Mutation (SNP) | VAF 45/150 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.055); catalogued as COSV50534212; called by muse, mutect2, varscan2
- SSMEM1 | c.290C>G p.P97R | Missense Mutation (SNP) | VAF 76/208 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.076); catalogued as COSV52833413; called by muse, mutect2, varscan2
- SULT1E1 | c.646G>T p.E216* | Nonsense Mutation (SNP) | VAF 38/133 reads (29%) | catalogued as COSV56946861; called by muse, mutect2, varscan2
- SVEP1 | c.2820A>T p.Q940H | Missense Mutation (SNP) | VAF 66/236 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.365); catalogued as COSV57034888; called by muse, varscan2
- TAS2R60 | c.895A>T p.S299C | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV60330698; called by muse, mutect2, varscan2
- TASOR | c.2903C>T p.S968F (on ENST00000355628 / NM_001365636.2; = p.S592F on NM_015224.3) | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs1319497651; called by muse, mutect2, varscan2
- TASOR | c.895C>G p.Q299E | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100843598; called by muse, mutect2
- TEK | c.487C>A p.H163N | Missense Mutation (SNP) | VAF 104/331 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as COSV66228732, COSV66228774; called by muse, mutect2, varscan2
- TENM2 | c.1613C>A p.A538D (on ENST00000518659 / NM_001122679.2; = p.A306D on NM_001080428.3) | Missense Mutation (SNP) | VAF 36/147 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV69124778, COSV69128622; called by muse, mutect2, varscan2
- TFR2 | c.248C>T p.P83L | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.73); PolyPhen benign (0.112); catalogued as rs1174363144, COSV50514602; called by muse, varscan2
- TGM7 | c.365T>C p.I122T | Missense Mutation (SNP) | VAF 66/195 reads (34%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.575); catalogued as rs1315264516, COSV71772738; called by muse, mutect2, varscan2
- TM6SF2 | c.136C>A p.L46M | Missense Mutation (SNP) | VAF 72/188 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.265); catalogued as COSV66985167; called by muse, mutect2, varscan2
- TMEM247 | c.386G>C p.R129P | Missense Mutation (SNP) | VAF 66/192 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71363632; called by muse, varscan2
- TPR | c.6064A>T p.M2022L | Missense Mutation (SNP) | VAF 62/376 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66600977; called by muse, mutect2, varscan2
- TRDN | c.1457C>T p.S486F | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); catalogued as rs1272823526, COSV62119971; called by muse, mutect2, varscan2
- TRIO | c.5722G>T p.E1908* | Nonsense Mutation (SNP) | VAF 104/344 reads (30%) | catalogued as COSV60082592; called by muse, varscan2
- TSPEAR | c.727C>A p.P243T | Missense Mutation (SNP) | VAF 68/216 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV59960112, COSV59979527; called by muse, mutect2, varscan2
- TTC21B | c.3843A>T p.R1281S | Missense Mutation (SNP) | VAF 63/205 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); catalogued as COSV54629932; called by muse, mutect2, varscan2
- TTC7B | c.2209G>A p.G737S | Missense Mutation (SNP) | VAF 123/352 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs1395637444, COSV60630003; called by muse, mutect2, varscan2
- URGCP | c.175G>T p.E59* (on ENST00000453200 / NM_001077663.3; = p.E50* on NM_017920.4) | Nonsense Mutation (SNP) | VAF 35/125 reads (28%) | catalogued as COSV56247122, COSV99787092; called by muse, mutect2, varscan2
- USF3 | c.3011T>C p.L1004S | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as COSV57072090; called by muse, mutect2, varscan2
- USP29 | c.1727C>A p.P576Q | Missense Mutation (SNP) | VAF 46/72 reads (64%) | SIFT tolerated (0.35); PolyPhen benign (0.174); catalogued as COSV54142183; called by muse, mutect2, varscan2
- VRTN | c.781C>G p.L261V | Missense Mutation (SNP) | VAF 65/169 reads (38%) | SIFT tolerated (0.74); PolyPhen benign (0.075); catalogued as COSV56440690; called by muse, mutect2, varscan2
- WDR27 | c.1930A>T p.I644L | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.036); catalogued as COSV61208052; called by muse, mutect2, varscan2
- WDR87 | c.6565G>T p.V2189L | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.342); catalogued as COSV58197682; called by muse, mutect2, varscan2
- WDR90 | c.5143G>A p.G1715S | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.511); catalogued as rs527771278; called by muse, mutect2, varscan2
- ZFP82 | c.332G>T p.G111V | Missense Mutation (SNP) | VAF 52/119 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.71); catalogued as COSV67565190; called by muse, mutect2, varscan2
- ZMYM2 | c.3184G>T p.D1062Y | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV101243972, COSV67033737; called by muse, mutect2, varscan2
- ZNF229 | c.999C>A p.N333K | Missense Mutation (SNP) | VAF 46/140 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as COSV52161507; called by muse, mutect2
- ZYX | c.781G>A p.A261T | Missense Mutation (SNP) | VAF 51/166 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV59556319; called by muse, mutect2, varscan2
- ABCA1 | c.422-1G>C p.X141_splice | Splice Site (SNP) | VAF 79/196 reads (40%) | called by muse, varscan2
- ACR | c.1189G>T p.G397W | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.615); called by mutect2, varscan2
- ADAMTS12 | c.116A>T p.D39V | Missense Mutation (SNP) | VAF 59/138 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- C3orf49 | c.742C>A p.H248N | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CALCR | c.430-1G>C p.X144_splice | Splice Site (SNP) | VAF 25/76 reads (33%) | called by muse, mutect2, varscan2
- CPS1 | c.76C>A p.H26N | Missense Mutation (SNP) | VAF 16/257 reads (6%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); called by muse, mutect2
- CPXM2 | c.631C>G p.P211A | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT tolerated, low confidence (0.3); called by muse, mutect2, varscan2
- CREBZF | c.*287+1G>A | Splice Site (SNP) | VAF 16/156 reads (10%) | called by muse, mutect2, varscan2
- CTAGE1 | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 76/258 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- CYP27C1 | c.1007T>G p.L336R | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- DGKK | c.2979C>A p.C993* | Nonsense Mutation (SNP) | VAF 24/36 reads (67%) | called by muse, mutect2, varscan2
- DHX9 | c.3680G>C p.R1227T | Missense Mutation (SNP) | VAF 135/801 reads (17%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- E2F8 | c.45G>C p.R15S | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FAM83G | c.121del p.R41Afs*104 | Frame Shift Del (DEL) | VAF 39/130 reads (30%) | called by mutect2, pindel, varscan2
- GPBAR1 | c.409C>T p.L137F | Missense Mutation (SNP) | VAF 63/186 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- HTR3E | c.994del p.L332Cfs*51 (on ENST00000415389 / NM_001256613.1; = p.L347Cfs*51 on NM_182589.2) | Frame Shift Del (DEL) | VAF 79/290 reads (27%) | called by mutect2, varscan2
- HYDIN | c.7600del p.E2534Sfs*36 | Frame Shift Del (DEL) | VAF 48/169 reads (28%) | called by mutect2, pindel, varscan2
- IKZF1 | c.484del p.R162Gfs*31 | Frame Shift Del (DEL) | VAF 34/101 reads (34%) | called by mutect2, pindel, varscan2
- LHX4 | c.460G>C p.E154Q | Missense Mutation (SNP) | VAF 95/507 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- MUC5AC | c.14036A>G p.E4679G | Missense Mutation (SNP) | VAF 67/244 reads (27%) | SIFT deleterious (0.02); called by muse, mutect2, varscan2
- OR11A1 | c.529C>A p.Q177K | Missense Mutation (SNP) | VAF 32/272 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, varscan2
- PDE6A | c.2317C>G p.Q773E | Missense Mutation (SNP) | VAF 108/305 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PRR5 | c.323-6C>G | Splice Region (SNP) | VAF 44/151 reads (29%) | called by muse, mutect2, varscan2
- PSD3 | c.89G>T p.R30L | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTCHD3 | c.1481_1483del p.T494del | In Frame Del (DEL) | VAF 46/190 reads (24%) | called by pindel, varscan2
- PTPN2 | c.563C>T p.S188L | Missense Mutation (SNP) | VAF 71/297 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- QRFPR | c.115G>C p.E39Q | Missense Mutation (SNP) | VAF 49/139 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- RPS6KB2 | c.466C>G p.L156V | Missense Mutation (SNP) | VAF 58/208 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- SLC25A41 | c.495C>G p.I165M | Missense Mutation (SNP) | VAF 63/133 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- SLC27A6 | c.1321del p.Y441Ifs*25 | Frame Shift Del (DEL) | VAF 63/216 reads (29%) | called by mutect2, pindel, varscan2
- SLC5A12 | c.1459C>A p.P487T | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, varscan2
- SPATA31A1 | c.3702G>T p.Q1234H | Missense Mutation (SNP) | VAF 159/639 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- SPHK2 | c.1052G>A p.R351K | Missense Mutation (SNP) | VAF 83/139 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- SUZ12 | c.673G>T p.G225* | Nonsense Mutation (SNP) | VAF 65/180 reads (36%) | called by muse, mutect2, varscan2
- TBC1D24 | c.688G>A p.D230N | Missense Mutation (SNP) | VAF 96/351 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TEX11 | c.714T>A p.Y238* (on ENST00000344304; = p.Y223* on NM_031276.3) | Nonsense Mutation (SNP) | VAF 52/73 reads (71%) | called by muse, mutect2, varscan2
- WDR70 | c.565G>C p.G189R | Missense Mutation (SNP) | VAF 51/121 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- YWHAG | c.327del p.K110Rfs*15 | Frame Shift Del (DEL) | VAF 60/230 reads (26%) | called by mutect2, pindel, varscan2
- ZBTB18 | c.436G>A p.D146N | Missense Mutation (SNP) | VAF 64/333 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- ZNF98 | c.1709G>T p.G570V | Missense Mutation (SNP) | VAF 47/181 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- ABCA13 | c.13692G>C p.S4564= | Silent (SNP) | VAF 38/104 reads (37%) | catalogued as COSV68946075; called by muse, mutect2, varscan2
- ACSM2B | c.1185A>T p.I395= | Silent (SNP) | VAF 32/90 reads (36%) | catalogued as COSV61657612; called by muse, mutect2, varscan2
- AKT1 | c.1290G>T p.T430= | Silent (SNP) | VAF 43/113 reads (38%) | catalogued as COSV62573104; called by muse, mutect2, varscan2
- ANK2 | c.11691G>A p.K3897= | Silent (SNP) | VAF 126/380 reads (33%) | catalogued as COSV52158121; called by muse, mutect2
- ATP8B2 | c.1818C>T p.S606= (on ENST00000672630; = p.S573= on NM_001367934.1 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 212/357 reads (59%) | catalogued as COSV59245801; called by muse, mutect2, varscan2
- CASS4 | c.831C>T p.S277= | Silent (SNP) | VAF 39/116 reads (34%) | called by muse, mutect2, varscan2
- CBFA2T2 | c.1449G>T p.A483= | Silent (SNP) | VAF 62/221 reads (28%) | catalogued as COSV60798671; called by muse, mutect2, varscan2
- CDHR1 | c.177G>T p.G59= | Silent (SNP) | VAF 100/433 reads (23%) | called by muse, mutect2, varscan2
- CLIP2 | c.1194G>T p.L398= | Silent (SNP) | VAF 83/239 reads (35%) | catalogued as COSV56277706; called by muse, mutect2, varscan2
- DNAAF5 | c.1803C>T p.A601= | Silent (SNP) | VAF 38/106 reads (36%) | catalogued as rs1276444942, COSV52416322; called by muse, mutect2, varscan2
- DNAH12 | c.9168C>T p.S3056= (on ENST00000351747; = p.S3924= on NM_001366028.2) | Silent (SNP) | VAF 55/162 reads (34%) | catalogued as COSV61058358; called by muse, mutect2, varscan2
- DPY19L3 | c.1599G>T p.L533= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as COSV60476237; called by muse, mutect2, varscan2
- DSCAML1 | c.1738C>A p.R580= (on ENST00000321322; = p.R520= on NM_020693.4) | Silent (SNP) | VAF 65/155 reads (42%) | catalogued as rs1172397068, COSV100356299, COSV58389260; called by muse, mutect2, varscan2
- ERVFRD-1 | c.999C>T p.L333= | Silent (SNP) | VAF 71/581 reads (12%) | called by muse, mutect2, varscan2
- EVC2 | c.531G>A p.S177= | Silent (SNP) | VAF 81/265 reads (31%) | catalogued as rs146658261; called by muse, mutect2, varscan2
- FAM83B | c.1971G>A p.E657= | Silent (SNP) | VAF 35/228 reads (15%) | catalogued as rs371571539; called by muse, mutect2, varscan2
- FANCM | c.4935T>A p.R1645= | Silent (SNP) | VAF 56/160 reads (35%) | catalogued as COSV57500355; called by muse, mutect2, varscan2
- HERC2 | c.14100G>C p.L4700= | Silent (SNP) | VAF 72/234 reads (31%) | catalogued as COSV55320828; called by muse, mutect2, varscan2
- HERC2 | c.987C>G p.S329= | Silent (SNP) | VAF 60/181 reads (33%) | catalogued as COSV55320846; called by muse, mutect2, varscan2
- LHFPL5 | c.552C>G p.L184= | Silent (SNP) | VAF 113/724 reads (16%) | called by muse, mutect2, varscan2
- LRCH4 | c.1935G>T p.V645= | Silent (SNP) | VAF 28/88 reads (32%) | catalogued as rs566082625, COSV56166287, COSV99776349; called by muse, varscan2
- MAGI2 | c.3618A>G p.T1206= | Silent (SNP) | VAF 25/72 reads (35%) | called by muse, mutect2, varscan2
- MDM2 | c.474G>A p.L158= | Silent (SNP) | VAF 37/109 reads (34%) | catalogued as COSV50698958; called by muse, mutect2, varscan2
- MICALL2 | c.393G>A p.G131= | Silent (SNP) | VAF 10/38 reads (26%) | called by muse, varscan2
- MS4A12 | c.306C>T p.H102= | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as rs1258317633, COSV50015969; called by muse, mutect2, varscan2
- MUC4 | c.7749C>T p.S2583= | Silent (SNP) | VAF 84/470 reads (18%) | catalogued as rs1320498375; called by muse, varscan2
- MXRA5 | c.2106G>T p.S702= | Silent (SNP) | VAF 41/54 reads (76%) | catalogued as rs770091557, COSV54232979; called by muse, mutect2, varscan2
- NCAM1 | c.1948C>A p.R650= (on ENST00000316851 / NM_181351.5; = p.R640= on NM_000615.7) | Silent (SNP) | VAF 40/100 reads (40%) | catalogued as COSV57515280; called by muse, mutect2, varscan2
- NCAM1 | c.2097G>C p.V699= (on ENST00000316851 / NM_181351.5; = p.V689= on NM_000615.7) | Silent (SNP) | VAF 19/91 reads (21%) | catalogued as COSV57515306, COSV57516449; called by muse, mutect2, varscan2
- NPBWR2 | c.270C>T p.A90= | Silent (SNP) | VAF 75/206 reads (36%) | catalogued as rs746990677, COSV63900057; called by muse, mutect2, varscan2
- OR11A1 | c.607C>T p.L203= | Silent (SNP) | VAF 56/426 reads (13%) | called by muse, varscan2
- PANK1 | c.1116T>A p.L372= (on ENST00000307534 / NM_148977.2; = p.L147= on NM_138316.4) | Silent (SNP) | VAF 68/228 reads (30%) | catalogued as COSV56807807; called by muse, mutect2, varscan2
- PIK3R4 | c.2415G>A p.V805= | Silent (SNP) | VAF 39/140 reads (28%) | catalogued as rs764804731, COSV63240619; called by muse, mutect2, varscan2
- PLPP4 | c.567C>A p.A189= | Silent (SNP) | VAF 28/152 reads (18%) | catalogued as COSV64827677; called by muse, mutect2, varscan2
- RAG1 | c.2034C>A p.L678= | Silent (SNP) | VAF 135/346 reads (39%) | called by muse, mutect2, varscan2
- RBM11 | c.105A>G p.P35= | Silent (SNP) | VAF 48/143 reads (34%) | catalogued as rs765463921, COSV68748076; called by muse, mutect2, varscan2
- RELN | c.3468G>A p.Q1156= | Silent (SNP) | VAF 139/372 reads (37%) | catalogued as rs748669801, COSV58999089; called by muse, mutect2, varscan2
- RTTN | c.1422C>T p.I474= | Silent (SNP) | VAF 34/98 reads (35%) | catalogued as rs779011598, COSV55344017; called by muse, mutect2, varscan2
- SLC16A3 | c.1188C>T p.L396= | Silent (SNP) | VAF 62/121 reads (51%) | catalogued as rs762495427, COSV58364423; called by muse, mutect2, varscan2
- SLC39A13 | c.603G>A p.P201= | Silent (SNP) | VAF 97/292 reads (33%) | catalogued as rs372236399; called by muse, mutect2, varscan2
- TECRL | c.432C>T p.T144= | Silent (SNP) | VAF 31/94 reads (33%) | catalogued as COSV67086832, COSV67090948; called by muse, mutect2, varscan2
- THBS2 | c.831C>A p.V277= | Silent (SNP) | VAF 53/94 reads (56%) | catalogued as COSV64678505; called by muse, mutect2, varscan2
- TMEM18 | c.309G>A p.V103= | Silent (SNP) | VAF 42/124 reads (34%) | catalogued as COSV55243810; called by muse, mutect2, varscan2
- UNC5CL | c.1422C>G p.L474= | Silent (SNP) | VAF 145/304 reads (48%) | catalogued as COSV55109747; called by muse, mutect2, varscan2
- WDR7 | c.2874G>T p.R958= | Silent (SNP) | VAF 110/308 reads (36%) | catalogued as COSV54352131; called by muse, mutect2, varscan2
- ZAN | c.5799C>A p.L1933= | Silent (SNP) | VAF 56/130 reads (43%) | called by muse, mutect2, varscan2
- ZMYM2 | c.3183T>C p.S1061= | Silent (SNP) | VAF 24/88 reads (27%) | catalogued as rs1309732267, COSV67033725; called by muse, mutect2, varscan2
- AC007218.1 | n.247G>T | RNA (SNP) | VAF 18/99 reads (18%) | called by muse, mutect2, varscan2
- AC024940.1 | n.4621C>A | RNA (SNP) | VAF 6/22 reads (27%) | called by muse, mutect2
- AL033381.1 | n.368C>A | RNA (SNP) | VAF 191/296 reads (65%) | called by muse, mutect2, varscan2
- ANKRD26P1 | n.672G>T | RNA (SNP) | VAF 20/51 reads (39%) | catalogued as rs751852651; called by muse, mutect2, varscan2
- AP000943.2 | n.52+11166C>A | Intron (SNP) | VAF 40/103 reads (39%) | called by muse, mutect2, varscan2
- BAGE2 | n.286G>T | RNA (SNP) | VAF 68/763 reads (9%) | called by muse, mutect2
- BHLHE41 | c.234+36_234+37insT | Intron (INS) | VAF 30/98 reads (31%) | called by mutect2, pindel, varscan2
- C22orf34 | n.697C>A | RNA (SNP) | VAF 11/38 reads (29%) | called by muse, mutect2, varscan2
- CDKN2A | c.150+67G>T | Intron (SNP) | VAF 109/340 reads (32%) | called by muse, mutect2, varscan2
- COL24A1 | c.4782+1080A>G | Intron (SNP) | VAF 43/141 reads (30%) | called by muse, mutect2, varscan2
- DCHS2 | n.2604G>T | RNA (SNP) | VAF 18/66 reads (27%) | catalogued as COSV59724679; called by muse, mutect2, varscan2
- DMAC2L | chr14:50332194 C>A | 3'Flank (SNP) | VAF 87/231 reads (38%) | called by muse, mutect2, varscan2
- FLJ40288 | n.888C>A | RNA (SNP) | VAF 38/119 reads (32%) | called by muse, mutect2, varscan2
- FMO3 | c.133-1989C>A | Intron (SNP) | VAF 124/184 reads (67%) | catalogued as rs191927458; called by muse, mutect2, varscan2
- GTF2IRD2P1 | n.1901G>T | RNA (SNP) | VAF 146/386 reads (38%) | called by mutect2, varscan2
- GVINP1 | n.5411A>T | RNA (SNP) | VAF 28/95 reads (29%) | called by muse, mutect2, varscan2
- HSP90AB3P | n.590G>T | RNA (SNP) | VAF 82/248 reads (33%) | catalogued as rs749094376; called by muse, mutect2, varscan2
- ITPRID2 | c.257+25G>T | Intron (SNP) | VAF 49/132 reads (37%) | called by muse, mutect2, varscan2
- KCNQ2 | c.1247+42C>A | Intron (SNP) | VAF 38/82 reads (46%) | called by muse, varscan2
- KCTD15 | c.693+257C>A | Intron (SNP) | VAF 10/43 reads (23%) | called by muse, mutect2, varscan2
- KRT6A | c.912+33G>C | Intron (SNP) | VAF 153/434 reads (35%) | called by muse, mutect2, varscan2
- LRRC49 | c.194-408C>T | Intron (SNP) | VAF 45/206 reads (22%) | called by muse, mutect2, varscan2
- MIDEAS | c.2162+46T>A | Intron (SNP) | VAF 64/199 reads (32%) | called by muse, mutect2, varscan2
- MIR296 | n.71G>A | RNA (SNP) | VAF 52/125 reads (42%) | called by muse, mutect2, varscan2
- MTFR1L | chr1:25820283 A>T | 5'Flank (SNP) | VAF 59/230 reads (26%) | called by muse, mutect2, varscan2
- NACA | c.71-1291G>T | Intron (SNP) | VAF 8/31 reads (26%) | called by muse, mutect2, varscan2
- OR7E5P | n.171C>A | RNA (SNP) | VAF 80/202 reads (40%) | catalogued as rs752375652; called by muse, mutect2, varscan2
- PABPC1P2 | n.1034G>C | RNA (SNP) | VAF 85/252 reads (34%) | called by muse, mutect2, varscan2
- RNU6-389P | chr7:55687896 C>A | 3'Flank (SNP) | VAF 80/219 reads (37%) | called by muse, mutect2, varscan2
- SCGB1A1 | c.-5C>A | 5'UTR (SNP) | VAF 21/54 reads (39%) | called by muse, mutect2, varscan2
- SERPINA13P | n.537T>A | RNA (SNP) | VAF 28/78 reads (36%) | called by muse, mutect2, varscan2
- SPAG6 | c.122-4028C>A | Intron (SNP) | VAF 64/151 reads (42%) | catalogued as COSV57619768; called by muse, mutect2, varscan2
- TMC8 | c.298+105C>T | Intron (SNP) | VAF 36/143 reads (25%) | called by muse, mutect2, varscan2
- VCAN | c.4004-11G>T | Intron (SNP) | VAF 10/28 reads (36%) | catalogued as rs529024482; called by muse, varscan2
- ZSCAN32 | c.839-634G>T | Intron (SNP) | VAF 54/137 reads (39%) | catalogued as COSV59235030; called by mutect2, varscan2
